Somatic mutation profile of tumor specimen 0D8E1V from CCDI case PBBHGB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Giant cell glioblastoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.0 years (2,197 days).
Specimen 0D8E1V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c8a10de-7ebb-4308-b20f-c1293e06bfd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8E2P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d704a0c9-08c3-459e-8f23-3df6e5b77f4c

The open-access MAF lists 222 somatic variants for this specimen: 144 protein-altering or splice-affecting, 46 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 46, Intron 15, 3'UTR 8, Splice Site 7, Nonsense Mutation 6, 5'UTR 4, Frame Shift Del 3, RNA 2, 5'Flank 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MIB1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 155/500 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs778947880; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MORC2 | c.956G>A p.R319H (on ENST00000397641 / NM_001303256.3; = p.R257H on NM_014941.3) | Missense Mutation (SNP) | VAF 21/456 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.719); catalogued as rs1163530787; ClinVar: likely pathogenic; called by muse, mutect2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 92/201 reads (46%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.801+1del | Frame Shift Del (DEL) | VAF 236/384 reads (61%) | catalogued as rs1060500110; ClinVar: likely pathogenic; called by mutect2, varscan2
- RB1 | c.1961-1G>A p.X654_splice | Splice Site (SNP) | VAF 163/262 reads (62%) | hotspot (GDC flag); catalogued as CS030557, CS158876, COSV57300165, COSV57300718, COSV57303667; called by muse, mutect2, varscan2
- AC092143.1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 80/465 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs758721601; called by muse, mutect2, varscan2
- ADAM33 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 63/610 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs537682740; called by muse, mutect2, varscan2
- ADAMTS13 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 32/1074 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs782433445; called by muse, mutect2
- ADGRV1 | c.18217G>A p.V6073M | Missense Mutation (SNP) | VAF 95/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377173958, COSV67991452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 94/670 reads (14%) | catalogued as COSV62339755; called by mutect2, varscan2
- ARHGAP11A | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 205/326 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64380944; called by muse, varscan2
- ATG2B | c.4919G>A p.R1640Q | Missense Mutation (SNP) | VAF 39/484 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs759729158; called by muse, mutect2
- ATP1A1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 37/863 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1165006226; called by muse, mutect2
- BHLHA15 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 40/904 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99807132; called by muse, mutect2
- CACNA1I | c.6023G>A p.R2008Q | Missense Mutation (SNP) | VAF 26/724 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs942465126, COSV60816915; called by muse, mutect2
- CCR2 | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 19/461 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV99432615; called by muse, mutect2
- CFAP47 | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV100544972; called by muse, mutect2, varscan2
- COL22A1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 35/768 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1307448296; called by muse, mutect2
- COL4A6 | c.3808C>T p.R1270* | Nonsense Mutation (SNP) | VAF 57/313 reads (18%) | catalogued as rs750490238; called by muse, mutect2, varscan2
- CRADD | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 36/413 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs138134122; called by muse, mutect2
- DCAF8 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 180/903 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs768015097, COSV100470970; called by muse, mutect2, varscan2
- DCHS1 | c.4399G>A p.G1467S | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs1016984571; called by muse, mutect2
- DDI1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs772774679, COSV56367219; called by muse, mutect2
- DEFA5 | c.206C>G p.T69S | Missense Mutation (SNP) | VAF 145/286 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57962310; called by muse, mutect2, varscan2
- DNALI1 | c.539G>A p.R180H (on ENST00000296218; = p.R158H on NM_003462.5) | Missense Mutation (SNP) | VAF 70/705 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.362); catalogued as rs771741737; called by muse, mutect2, varscan2
- DSG1 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 216/401 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs140838956; called by muse, mutect2, varscan2
- DSP | c.8416G>A p.A2806T | Missense Mutation (SNP) | VAF 43/555 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as rs1005621727; called by muse, mutect2
- ELMO2 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 25/820 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as COSV51685014; called by muse, mutect2
- FBXO2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 106/659 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs1224069364; called by muse, mutect2, varscan2
- FMN2 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 90/954 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs576376829, COSV60425346, COSV60434479; called by muse, mutect2
- GLI2 | c.3124G>A p.D1042N (on ENST00000361492 / NM_001374353.1; = p.D1059N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/526 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs762818312, COSV58038867; called by muse, mutect2
- IL12RB2 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 86/956 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748707538, COSV52026908; called by muse, mutect2
- KCNH7 | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 108/516 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59784058; called by muse, mutect2, varscan2
- KDM8 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 330/722 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs534702057, COSV53731728; called by muse, mutect2, varscan2
- LAMP3 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 136/721 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs114675283; called by muse, mutect2, varscan2
- LOXHD1 | c.3350+1G>A p.X1117_splice | Splice Site (SNP) | VAF 48/490 reads (10%) | catalogued as rs1301706601; called by muse, mutect2
- LZTR1 | c.2248G>A p.G750S | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1359992200; called by muse, mutect2, varscan2
- MX1 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 212/880 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs372998034; called by muse, mutect2, varscan2
- MXRA5 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 44/523 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260557232; called by muse, mutect2
- MYH14 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 180/554 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs1338133983, COSV104386389, COSV99224227; called by muse, mutect2, varscan2
- NLRC3 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs199854307; called by muse, mutect2, varscan2
- NOSTRIN | c.1453G>A p.G485S (on ENST00000317647 / NM_001039724.4; = p.G407S on NM_052946.3) | Missense Mutation (SNP) | VAF 198/521 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58318931; called by muse, mutect2, varscan2
- NRAP | c.4277C>T p.A1426V (on ENST00000359988 / NM_001322945.2; = p.A1391V on NM_006175.4) | Missense Mutation (SNP) | VAF 43/757 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs751612141; called by muse, mutect2
- OR2T4 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 46/1744 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63544435; called by muse, mutect2
- OR51G1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429166, COSV58968600; called by muse, mutect2, varscan2
- PARP15 | c.2030C>T p.T677M (on ENST00000464300 / NM_001113523.3; = p.T443M on NM_152615.2) | Missense Mutation (SNP) | VAF 147/455 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs774977722; called by muse, mutect2, varscan2
- PATL2 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs951076370; called by muse, mutect2, varscan2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 121/1149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2, varscan2
- PCNX4 | c.3081G>C p.R1027S (on ENST00000406854 / NM_001330177.2; = p.R793S on NM_022495.5) | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58306884; called by muse, mutect2
- PDZD7 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 41/781 reads (5%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.922); catalogued as rs1052665117; ClinVar: uncertain significance; called by muse, mutect2
- PLEC | c.8308C>T p.L2770F (on ENST00000322810 / NM_201380.4; = p.L2660F on NM_000445.5) | Missense Mutation (SNP) | VAF 184/451 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as rs1247177731; called by muse, mutect2, varscan2
- PLEC | c.5156G>A p.R1719H (on ENST00000322810 / NM_201380.4; = p.R1609H on NM_000445.5) | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs781876093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLLP | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 30/838 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1406515938; called by muse, mutect2
- PRAMEF10 | c.744C>G p.Y248* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs761197311; called by mutect2, varscan2
- PTPN23 | c.4105C>T p.R1369C | Missense Mutation (SNP) | VAF 74/810 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs992872002, COSV55544624, COSV55544658; called by muse, mutect2
- RADIL | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 102/986 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs761566410; called by muse, mutect2
- RFX7 | c.1685G>A p.R562Q (on ENST00000559447 / NM_001368074.1; = p.R659Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/446 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1288018809, COSV100428798; called by muse, mutect2, varscan2
- SATB2 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as rs754582487; called by muse, mutect2
- SCN1B | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 245/705 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371646049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs558749829, COSV51807489; called by muse, mutect2, varscan2
- SDK1 | c.3812C>T p.T1271M | Missense Mutation (SNP) | VAF 201/781 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286533820; called by muse, mutect2, varscan2
- SLC19A1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 26/629 reads (4%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.488); catalogued as COSV100229328, COSV100229370; called by muse, mutect2
- SLC27A2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752117544, COSV51057583; called by muse, mutect2
- SPEG | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 82/475 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752154042, COSV56667516; called by muse, mutect2, varscan2
- TASOR2 | c.6314G>A p.R2105Q | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs748670160, COSV100050568, COSV60167612; called by muse, mutect2, varscan2
- TNC | c.5506G>A p.E1836K | Missense Mutation (SNP) | VAF 95/669 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs774393174; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3821G>A p.R1274H | Missense Mutation (SNP) | VAF 58/656 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs771071152, COSV64100744; called by muse, mutect2
- TPO | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 25/458 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs745582362, COSV61100594; called by muse, mutect2
- TRPM6 | c.3764A>T p.N1255I | Missense Mutation (SNP) | VAF 138/945 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs35378712; called by muse, mutect2, varscan2
- TRPV6 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 67/626 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs779037714; called by muse, mutect2, varscan2
- YPEL1 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 81/448 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1247081148, COSV58609322; called by muse, mutect2, varscan2
- ZFYVE1 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs369576622; called by muse, mutect2
- ZFYVE26 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 84/602 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs753557379; called by muse, mutect2, varscan2
- ZFYVE9 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 54/797 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.084); catalogued as rs201953822; called by muse, mutect2
- ZNF280A | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 404/683 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747270512, COSV57479878; called by muse, mutect2, varscan2
- ZNF319 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 54/706 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769724117; called by muse, mutect2
- AASS | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 36/1058 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2
- ACAP3 | c.1407+2T>C p.X469_splice | Splice Site (SNP) | VAF 31/913 reads (3%) | called by muse, mutect2
- ADH7 | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 34/684 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ANTXR2 | c.1116G>C p.K372N | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- AP2S1 | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 23/361 reads (6%) | called by muse, mutect2
- ATP1A1 | c.366A>C p.E122D | Missense Mutation (SNP) | VAF 105/990 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP2 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 32/664 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CBFA2T2 | c.895A>T p.I299F | Missense Mutation (SNP) | VAF 20/555 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- CIC | c.931+2T>C p.X311_splice | Splice Site (SNP) | VAF 32/577 reads (6%) | called by muse, mutect2
- CNTRL | c.4252G>T p.V1418L | Missense Mutation (SNP) | VAF 160/609 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CSGALNACT2 | c.927T>A p.Y309* | Nonsense Mutation (SNP) | VAF 91/374 reads (24%) | called by muse, mutect2, varscan2
- CSMD2 | c.5974A>T p.M1992L | Missense Mutation (SNP) | VAF 184/775 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP11B2 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 36/1003 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.111); called by muse, mutect2
- CYP2C9 | c.481+3G>A | Splice Region (SNP) | VAF 22/576 reads (4%) | called by muse, mutect2
- DEFB124 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 306/638 reads (48%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DNAAF3 | c.166G>T p.D56Y (on ENST00000524407 / NM_001256715.2; = p.D103Y on NM_178837.4) | Missense Mutation (SNP) | VAF 309/472 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPY19L4 | c.1912G>C p.A638P | Missense Mutation (SNP) | VAF 23/446 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- EIF2AK1 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 325/857 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EIF3I | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 168/862 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, varscan2
- FLG2 | c.7155C>A p.N2385K | Missense Mutation (SNP) | VAF 218/625 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- GLI3 | c.1538T>C p.F513S | Missense Mutation (SNP) | VAF 158/776 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GSAP | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 205/549 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- HELLS | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HSD11B1L | c.316+2T>C p.X106_splice | Splice Site (SNP) | VAF 18/434 reads (4%) | called by muse, mutect2
- HYAL3 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.037); called by muse, mutect2
- JAG2 | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 36/898 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAK3 | c.265T>A p.S89T | Missense Mutation (SNP) | VAF 34/797 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- JRKL | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 49/630 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2
- KIF16B | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 314/543 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF18A | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 272/502 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- KMT2E | c.4765G>A p.A1589T | Missense Mutation (SNP) | VAF 29/718 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.337); called by muse, mutect2
- LAT | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 28/665 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LIN37 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 101/465 reads (22%) | called by muse, mutect2, varscan2
- LRRC6 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 206/318 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MAVS | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 52/538 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- MROH1 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 272/422 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MUC5AC | c.6467G>A p.R2156Q | Missense Mutation (SNP) | VAF 30/816 reads (4%) | SIFT tolerated (0.64); called by muse, mutect2
- MUC5B | c.9017C>A p.T3006N | Missense Mutation (SNP) | VAF 56/1038 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- NLRP14 | c.2498A>T p.E833V | Missense Mutation (SNP) | VAF 158/448 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NOL6 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 30/1060 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUFIP1 | c.1227A>T p.K409N | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.109); called by muse, mutect2
- ODAM | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 24/774 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- PDGFRA | c.3167G>T p.S1056I | Missense Mutation (SNP) | VAF 58/789 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- PDILT | c.465A>T p.K155N | Missense Mutation (SNP) | VAF 104/626 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PDZRN3 | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHA8 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 220/612 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHG2 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2
- PNPLA3 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 67/667 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PRDM13 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 228/381 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRO | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 324/531 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM33 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 55/567 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ROS1 | c.3175A>T p.N1059Y | Missense Mutation (SNP) | VAF 25/613 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2
- SCN8A | c.4789A>G p.I1597V | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2
- SDF2 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 100/541 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SELENOI | c.215A>T p.D72V | Missense Mutation (SNP) | VAF 17/471 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC39A12 | c.1933T>A p.S645T (on ENST00000377369 / NM_001145195.2; = p.S608T on NM_152725.3) | Missense Mutation (SNP) | VAF 340/538 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMG7 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 343/1037 reads (33%) | called by muse, mutect2, varscan2
- SNRNP70 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 365/544 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SSR2 | c.550T>C p.*184Rext*30 | Nonstop Mutation (SNP) | VAF 18/516 reads (3%) | called by muse, mutect2
- SYVN1 | c.354G>C p.W118C | Missense Mutation (SNP) | VAF 49/1004 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- TERF1 | c.1039+1G>A p.X347_splice (on ENST00000276603 / NM_017489.3; = p.X327_splice on NM_003218.4) | Splice Site (SNP) | VAF 362/622 reads (58%) | called by muse, mutect2, varscan2
- TES | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 149/608 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM245 | c.2321G>T p.C774F | Missense Mutation (SNP) | VAF 23/808 reads (3%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.519); called by muse, mutect2
- TP53 | c.551_554del p.D184Afs*62 | Frame Shift Del (DEL) | VAF 206/340 reads (61%) | called by mutect2, varscan2
- TTLL10 | c.1070A>T p.Q357L (on ENST00000379289 / NM_001130045.2; = p.Q284L on NM_153254.3) | Missense Mutation (SNP) | VAF 30/988 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.312); called by muse, mutect2
- WIZ | c.2968C>A p.L990M (on ENST00000673675 / NM_001371589.1; = p.L167M on NM_001330395.4) | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFYVE26 | c.4278G>A p.W1426* | Nonsense Mutation (SNP) | VAF 23/600 reads (4%) | called by muse, mutect2
- ZNF638 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 23/633 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ABCC6 | c.1707G>T p.V569= | Silent (SNP) | VAF 100/694 reads (14%) | catalogued as COSV52747065; called by mutect2, varscan2
- ACADL | c.336G>T p.G112= | Silent (SNP) | VAF 42/382 reads (11%) | called by muse, mutect2, varscan2
- ACTRT1 | c.192G>A p.K64= | Silent (SNP) | VAF 24/375 reads (6%) | catalogued as COSV64419603; called by muse, mutect2
- AEBP1 | c.1110C>T p.G370= | Silent (SNP) | VAF 130/657 reads (20%) | catalogued as rs958515837; called by muse, mutect2, varscan2
- AFF2 | c.2661C>T p.A887= | Silent (SNP) | VAF 251/363 reads (69%) | called by muse, mutect2, varscan2
- AFF3 | c.1773C>T p.T591= | Silent (SNP) | VAF 33/588 reads (6%) | called by muse, mutect2
- ALOX5 | c.921C>T p.A307= | Silent (SNP) | VAF 78/550 reads (14%) | catalogued as rs763050647; called by muse, varscan2
- ANKRD36C | c.1344G>A p.K448= | Silent (SNP) | VAF 289/563 reads (51%) | called by muse, mutect2, varscan2
- C2CD6 | c.180G>T p.T60= | Silent (SNP) | VAF 40/562 reads (7%) | called by muse, mutect2
- CALHM5 | c.570G>A p.A190= | Silent (SNP) | VAF 72/459 reads (16%) | catalogued as rs755491538, COSV62067683; called by muse, mutect2, varscan2
- CPTP | c.528C>T p.N176= | Silent (SNP) | VAF 100/412 reads (24%) | catalogued as rs747710826, COSV59562840; called by muse, varscan2
- DAAM1 | c.687C>T p.A229= | Silent (SNP) | VAF 33/502 reads (7%) | catalogued as rs531300580; called by muse, mutect2
- DCLK1 | c.627G>C p.T209= | Silent (SNP) | VAF 298/482 reads (62%) | catalogued as COSV99709164; called by muse, mutect2, varscan2
- DNAH3 | c.9942C>T p.I3314= | Silent (SNP) | VAF 188/601 reads (31%) | catalogued as rs748161646, COSV54553880; called by muse, mutect2, varscan2
- DUS2 | c.22C>T p.L8= | Silent (SNP) | VAF 69/296 reads (23%) | called by muse, mutect2, varscan2
- FNTB | c.1074T>C p.R358= | Silent (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- HMCN1 | c.7602T>C p.F2534= | Silent (SNP) | VAF 185/863 reads (21%) | called by muse, mutect2, varscan2
- IGSF9B | c.426A>C p.T142= | Silent (SNP) | VAF 286/440 reads (65%) | called by muse, mutect2, varscan2
- IPO7 | c.915G>A p.L305= | Silent (SNP) | VAF 58/390 reads (15%) | called by muse, mutect2, varscan2
- IQSEC1 | c.1065G>A p.T355= | Silent (SNP) | VAF 26/534 reads (5%) | catalogued as rs773884376; called by muse, mutect2
- LAMA1 | c.3975G>A p.S1325= | Silent (SNP) | VAF 117/442 reads (26%) | catalogued as rs187196123; called by muse, mutect2, varscan2
- LTBP4 | c.2973C>T p.C991= (on ENST00000308370 / NM_001042544.1; = p.C954= on NM_003573.2) | Silent (SNP) | VAF 31/409 reads (8%) | catalogued as rs764232123, COSV52578490; called by muse, mutect2
- LZTR1 | c.1431G>A p.A477= | Silent (SNP) | VAF 103/493 reads (21%) | catalogued as rs767450866, COSV53146960; called by muse, mutect2, varscan2
- MUC17 | c.6924T>C p.T2308= | Silent (SNP) | VAF 26/557 reads (5%) | called by muse, mutect2
- MXRA5 | c.7008A>G p.R2336= | Silent (SNP) | VAF 105/486 reads (22%) | called by muse, varscan2
- NEGR1 | c.447C>T p.T149= | Silent (SNP) | VAF 138/664 reads (21%) | catalogued as rs375586274; called by muse, mutect2, varscan2
- NSD2 | c.4044G>A p.P1348= | Silent (SNP) | VAF 34/664 reads (5%) | catalogued as rs553381346; called by muse, mutect2
- NTNG2 | c.402C>T p.T134= | Silent (SNP) | VAF 23/839 reads (3%) | catalogued as rs1382742920, COSV62364219; called by muse, mutect2
- OAT | c.1125A>G p.G375= | Silent (SNP) | VAF 19/514 reads (4%) | called by muse, mutect2
- OR2W3 | c.444C>A p.T148= | Silent (SNP) | VAF 43/747 reads (6%) | called by muse, mutect2
- PCSK5 | c.3003C>T p.C1001= | Silent (SNP) | VAF 58/919 reads (6%) | called by muse, mutect2
- PEPD | c.507C>T p.F169= | Silent (SNP) | VAF 24/255 reads (9%) | catalogued as rs377714630, COSV54889641; called by muse, mutect2, varscan2
- PIK3R5 | c.1548G>A p.T516= | Silent (SNP) | VAF 182/561 reads (32%) | catalogued as rs780537367, COSV52651094; called by muse, mutect2, varscan2
- PMVK | c.60C>T p.S20= | Silent (SNP) | VAF 276/810 reads (34%) | catalogued as rs545863134; called by muse, mutect2, varscan2
- PTPRF | c.4098G>A p.T1366= | Silent (SNP) | VAF 302/1147 reads (26%) | catalogued as rs1435716496; called by muse, mutect2, varscan2
- RAB3IP | c.804G>A p.T268= (on ENST00000550536 / NM_175623.4; = p.T252= on NM_022456.5) | Silent (SNP) | VAF 79/418 reads (19%) | catalogued as rs150996361; called by muse, mutect2, varscan2
- RAD54L2 | c.696C>G p.G232= | Silent (SNP) | VAF 26/594 reads (4%) | called by muse, mutect2
- REST | c.2790G>A p.E930= | Silent (SNP) | VAF 294/493 reads (60%) | called by muse, mutect2, varscan2
- RGPD8 | c.237C>T p.A79= | Silent (SNP) | VAF 22/892 reads (2%) | catalogued as rs1167760814; called by muse, mutect2
- SCIN | c.795G>T p.V265= (on ENST00000297029 / NM_001112706.3; = p.V18= on NM_033128.3) | Silent (SNP) | VAF 334/934 reads (36%) | called by muse, mutect2, varscan2
- SERPIND1 | c.201C>T p.N67= | Silent (SNP) | VAF 298/881 reads (34%) | catalogued as rs772705090, COSV99300145; called by muse, mutect2, varscan2
- SYT16 | c.1050G>A p.K350= | Silent (SNP) | VAF 216/349 reads (62%) | catalogued as rs1352458170, COSV101413536; called by muse, mutect2, varscan2
- TMEM181 | c.822G>T p.L274= | Silent (SNP) | VAF 34/750 reads (5%) | called by muse, mutect2
- TNFRSF17 | c.312G>A p.L104= | Silent (SNP) | VAF 121/736 reads (16%) | called by muse, mutect2, varscan2
- TRIM26 | c.201C>T p.P67= | Silent (SNP) | VAF 17/564 reads (3%) | catalogued as rs367664883, COSV68963070; called by muse, mutect2
- UBR5 | c.4731T>A p.G1577= | Silent (SNP) | VAF 10/297 reads (3%) | catalogued as COSV55299973; called by muse, mutect2
- ABHD11 | c.289-54G>C | Intron (SNP) | VAF 110/268 reads (41%) | called by muse, mutect2, varscan2
- AC138207.8 | n.481G>A | RNA (SNP) | VAF 64/180 reads (36%) | catalogued as rs1336778181; called by mutect2, varscan2
- AQP5 | chr12:49967199 C>A | 3'Flank (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- ARMC5 | chr16:31458352 C>T | 5'Flank (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- ARSJ | c.*32del | 3'UTR (DEL) | VAF 278/448 reads (62%) | catalogued as COSV59537827; called by mutect2, varscan2
- C2CD2L | c.571-27G>T | Intron (SNP) | VAF 78/127 reads (61%) | called by muse, mutect2, varscan2
- C2orf83 | n.423C>A | RNA (SNP) | VAF 155/350 reads (44%) | called by muse, varscan2
- CARMIL3 | chr14:24050956 G>A | 5'Flank (SNP) | VAF 21/455 reads (5%) | catalogued as rs951753117; called by muse, mutect2
- CEP170 | c.-36C>T | 5'UTR (SNP) | VAF 15/322 reads (5%) | catalogued as rs371269335; called by muse, mutect2
- DVL1 | c.1054+43C>T | Intron (SNP) | VAF 22/476 reads (5%) | catalogued as rs914166942, COSV59564762; called by muse, mutect2
- EPN1 | c.*13764T>C | 3'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as rs1270402629; called by muse, mutect2, varscan2
- GOSR1 | c.440+65G>A | Intron (SNP) | VAF 27/113 reads (24%) | catalogued as rs1220474475; called by muse, mutect2, varscan2
- KRT28 | c.*50C>A | 3'UTR (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- LCT | c.908-18C>A | Intron (SNP) | VAF 179/283 reads (63%) | catalogued as COSV99930215; called by muse, mutect2, varscan2
- MGAT5B | c.69-160del | Intron (DEL) | VAF 36/88 reads (41%) | catalogued as rs1008588794; called by mutect2, varscan2
- MRM3 | c.*5G>A | 3'UTR (SNP) | VAF 20/355 reads (6%) | called by muse, mutect2
- MYH6 | c.1581+68T>A | Intron (SNP) | VAF 127/215 reads (59%) | called by muse, mutect2, varscan2
- NFATC1 | c.-27G>T | 5'UTR (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- PAN2 | c.2709+13A>G | Intron (SNP) | VAF 45/330 reads (14%) | called by muse, mutect2, varscan2
- PIK3CG | c.*64G>A | 3'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as rs1409539582, COSV63255686; called by muse, mutect2, varscan2
- PNPT1 | c.1822+34G>A | Intron (SNP) | VAF 38/221 reads (17%) | catalogued as rs775156989; called by muse, mutect2, varscan2
- POR | c.*150C>T | 3'UTR (SNP) | VAF 47/1032 reads (5%) | catalogued as rs1329210874; called by muse, mutect2
- PPIE | c.201+51A>G | Intron (SNP) | VAF 116/299 reads (39%) | called by muse, mutect2, varscan2
- PSMC3 | c.159+54C>T | Intron (SNP) | VAF 42/124 reads (34%) | called by muse, mutect2, varscan2
- PTGS1 | c.94+462A>G | Intron (SNP) | VAF 72/172 reads (42%) | called by muse, mutect2, varscan2
- RIMBP3 | c.-26T>C | 5'UTR (SNP) | VAF 14/20 reads (70%) | called by mutect2, varscan2
- SPARC | c.*212C>T | 3'UTR (SNP) | VAF 7/92 reads (8%) | catalogued as rs1194820379; called by muse, mutect2
- SPATA6L | c.226+9600T>C | Intron (SNP) | VAF 19/524 reads (4%) | called by muse, mutect2
- ST3GAL2 | c.-26G>T | 5'UTR (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- TBL3 | c.94-30G>A | Intron (SNP) | VAF 15/474 reads (3%) | called by muse, mutect2
- TCTN2 | c.*72C>T | 3'UTR (SNP) | VAF 62/98 reads (63%) | called by muse, mutect2, varscan2
- TPM3 | c.567-93dup | Intron (INS) | VAF 40/109 reads (37%) | called by mutect2, varscan2
